TCGA case TCGA-XF-A9T0 — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Southern California. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5f5c1775-a908-483d-8a77-b902c5b7570e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Alive.

Diagnoses (3)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 69.0 years (25,190 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 799 days (2.2 years).
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: No; Lymph nodes positive: 0; Lymph nodes tested: 79; Lymphatic invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Carcinoma, NOS: Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; AJCC pathologic T: T2a.
3. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; Age at diagnosis: 69.1 years (25,255 days); Days to diagnosis: 65 days; AJCC staging edition: 4th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 65 days; Treatment anatomic sites: Prostate.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 799 days (2.2 years); Disease response: Tumor Free.
- Karnofsky performance status: 90.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 82 kg; Height: 178 cm; BMI: 25.9.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.
- Occupation type: Administration Professionals.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XF-A9T0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 770 mg.
  Slide TCGA-XF-A9T0-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XF-A9T0-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XF-A9T0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Occupation current: Campus Supervisor; Occupation primary: Administration/Contracting; Occupation primary industry: Military Industry; Tobacco smoking history indicator: 5; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: No; Incidental prostate cancer indicator: Yes; AJCC path pathologic T incidental prostate: pT2a; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Stage record, Gleason grading: Gleason score: 7.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form, Surgery: Other malignancy surgery type: Prostatectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 799 days; disease-specific survival: no event (censored), 799 days; disease-free interval: no event (censored), 799 days; progression-free interval: no event (censored), 799 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XF-A9T0-01A-11D-A390-01): tumor purity 0.76, ploidy 3.88, whole-genome doublings 1.
